HCMI case HCM-CSHL-0666-C24 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Other and unspecified parts of biliary tract. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/91ebd37e-c8ea-4e03-ae01-35d111678dbd

Demographics
Sex at birth: female; Year of birth: 1949; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C24.1; Tissue or organ of origin: Ampulla of Vater; Classification of tumor: primary; Age at diagnosis: 70.6 years (25,775 days); AJCC staging edition: 8th; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Tumor grade: G2; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Prior treatment: No; Residual disease: R0; Tumor confined to organ of origin: No.
   Pathology details: Lymph nodes positive: 0; Lymph nodes tested: 26; Perineural invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: -31 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.
2. Tubulovillous adenoma, NOS: ICD-O-3 morphology code: 8263/0; ICD-10 code: C24.1; Site of resection or biopsy: Ampulla of Vater; Classification of tumor: Premalignant.

Follow-up (2 entries)
- Days to follow up: 484 days (1.3 years); Disease response: Complete Response; Progression or recurrence: No.
- Follow-up contact recording only the day: day 255.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 59 kg; Height: 156 cm; BMI: 24.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0666-C24-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-CSHL-0666-C24-31A: Sample type: Neoplasms of Uncertain and Unknown Behavior; Tissue type: Tumor; Tumor descriptor: Premalignant; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0666-C24-31A-01-S1-HE: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 100; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 5.
  Slide HCM-CSHL-0666-C24-31A-01-S2-HE: Section location: Bottom; Percent tumor cells: 0; Percent tumor nuclei: 80; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 90; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 5.
- Sample HCM-CSHL-0666-C24-85P: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Premalignant; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
